Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A4FO, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A4FO-01A (Primary Tumor).

[page 1 of 3]
LABORATORY MEDICINE PROG

Surgical Pathology Consultation Report

Patient Name:

MRN:

DOB:

Gender:

HCN:

Ordering MD:

Copy To:

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Specimen(s) Received

1. Thyroid: Total thyroid stitch marks upper pole left lobe, fresh for tumour banking

Diagnosis

Bilateral and multifocal papillary carcinoma, dominant classical variant with focal tall cell change (<5%), 1.1 cm, left lobe;
underlying chronic lymphocytic thyroiditis: Thyroid
No pathological diagnosis: Lymph nodes, 2, right perithyroidal
No pathological diagnosis: Lymph node, 1, isthmus
No pathological diagnosis: Lymph nodes, 2, left perithyroidal
Extensive cautery artefact, no evidence of malignancy: Lymph node, 1, left perithyroidal
- Total thyroidectomy specimen

Synoptic Data

Procedure:	Total thyroidectomy
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Right lobe: 3.6 cm 2.7 cm 1.3 cm Left lobe: 4.0 cm 3.0 cm 1.5 cm Isthmus +/- pyramidal lobe: 2.1 cm 2.0 cm 0.5 cm
Specimen Weight:	15.5 g
Tumor Focality:	Multifocal, bilateral Multifocal, midline (isthmus)
----- DOMINANT TUMOR -----	
Tumor Laterality:	Left lobe
Tumor Size:	Greatest dimension: 1.1cm Additional dimension: 0.9 cm
Histologic Type:	Papillary carcinoma, classical (usual)

ICD-0-3
Carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9
lw
10/2/12

[page 2 of 3]
Surgical Pathology Consultation Report

	Papillary carcinoma, other variant: with focal tall cell change (<5%)
	Classical (papillary) architecture
	Classical cytomorphology
	Tall cell cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	Partially encapsulated
Tumor Capsular Invasion:	Present, extent minimal
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
----- SECOND TUMOR -----	
Tumor Locality:	Right lobe
Tumor Size:	Greatest dimension: 1.0 cm
Histologic Type:	Papillary carcinoma, classical (usual)
	Papillary carcinoma, microcarcinoma (occult, small or microscopic variant)
	Papillary carcinoma, other: with focal Warthin-like change
	Classical (papillary) architecture
	Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	Partially encapsulated
Tumor Capsular Invasion:	Present, extent minimal
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	m (multiple primary tumors)
Primary Tumor (pT):	pT1b: Tumor more than 1 cm but not more than 2 cm in greatest dimension, limited to the thyroid
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis Number of regional lymph nodes examined: 6 Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Thyroiditis, other: chronic lymphocytic thyroiditis Other: additional bilateral and isthmic multiple papillary microcarcinomas ranging from 0.05 cm to 0.6 cm

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:

Gross Description

The specimen labeled with the patient's name and as "Thyroid: Total thyroid stitch marks upper pole left lobe, fresh for tumor banking" consists of an oriented thyroidectomy specimen that weighs 15.5 g. The right lobe measures 3.6 cm SI x 2.7 cm ML x 1.3 cm AP, the left lobe measures 4.0 cm SI x 3.0 cm ML x 1.5 cm AP and the isthmus measures 2.0 cm SI x 2.1 cm ML x 0.5 cm AP. The external surfaces have fibrous adhesions and are painted with silver nitrate. No parathyroid glands or no lymph nodes are identified grossly. The lower left lobe contains a well delineated partly calcified nodule that measures 1.1 cm SI x 0.9 cm ML x 0.7 cm AP. The remainder of the thyroid tissue is grossly unremarkable. Sections of left lobe nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

1A-F right lobe, superior to inferior
1G-H isthmus
1I-N left lobe, superior to inferior

[page 3 of 3]
Surgical Pathology Consultation Report

Source: NCI Genomic Data Commons file 51620af7-eb35-4277-b71a-da423dcc26fc (TCGA-EM-A4FO.91A90308-307B-4AF2-98F3-AFFF5153C248.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).